Gene-level copy-number profile of tumor specimen TCGA-A7-A26H-01A from TCGA case TCGA-A7-A26H, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.3 years (26,423 days).
Specimen TCGA-A7-A26H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.3b70861d-2c7b-4139-a282-6cfdd8aa4386.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A26H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/96abf3f7-6983-4218-9db9-593d71aeef06

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,198; copy number 3: 1,009; copy number 4: 44,009; copy number 5: 1,497; copy number 6: 3,806; copy number 7: 2,616; copy number 8: 2,438; copy number 9: 23; copy number 10: 2,043; copy number 11: 39; copy number 12: 105; copy number 13: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A26H-01A-11D-A166-01): tumor purity 0.63, ploidy 2.29, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,247 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,513,377–248,919,946, 1,952 genes, copy number 10 (broad region; genes not listed).
- chr7:86,216,785–89,754,726, 39 genes, copy number 11: SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P.
- chr8:72,019,917–73,325,281, 23 genes, copy number 9 (within-gene range 7–9): TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10.
- chr17:49,085,511–49,789,180, 28 genes, copy number 10: B4GALNT2P1, B4GALNT2, AC069454.1, GNGT2, ABI3, PHOSPHO1, FLJ40194, MIR6129, ZNF652, AC091180.2, AC091180.5, AC091180.4, AC091180.1, PHB, AC091180.3, Y_RNA, EIF4EP2, LINC02075, AC015656.1, NGFR, AC006487.1, MIR6165, AC006487.2, NXPH3, SPOP, SLC35B1, AC015795.1, FAM117A.
- chr17:49,795,343–49,795,669, 1 gene, copy number 10: SRP14P3.
- chr17:50,634,777–52,899,588, 36 genes, copy number 10 (within-gene range 8–10): ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1, LINC01982, LINC02089.
- chr17:53,276,760–54,365,634, 1 gene, copy number 13 (within-gene range 3–13): AC034268.2.
- chr17:53,681,630–56,595,611, 30 genes, copy number 10–13: AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG.
- chr17:57,253,236–58,219,605, 32 genes, copy number 13: AC091181.2, MSI2, AC091181.1, AC015883.1, AC007431.2, AC007431.3, AC007431.1, RN7SL449P, RNU7-134P, CCDC182, AC015845.2, RN7SKP94, MRPS23, CUEDC1, AC015845.1, AC015813.4, VEZF1, AC015813.7, AC015813.2, AC015813.1, SRSF1, AC015813.5, AC015813.8, AC015813.3, DYNLL2, AC015813.6, OR4D1, MSX2P1, OR4D2, EPX, AC005962.1, MKS1.
- chr17:58,755,854–62,140,639, 105 genes, copy number 12 (within-gene range 6–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
